TCGA case TCGA-29-1775 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4a3fca9-723a-47f5-a49d-b3acb71c04a7

Demographics
Sex at birth: female; Race: white; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 51.9 years (18,943 days); Year of diagnosis: 2008; Method of diagnosis: Incisional Biopsy; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 376 days (1.0 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 166 days; Number of cycles: 6; Treatment dose: 4,290 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 166 days; Number of cycles: 6; Treatment dose: 2,040 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial; Treatment intent type: Adjuvant; Days to treatment start: 114 days; Days to treatment end: 320 days; Number of cycles: 10; Treatment dose: 11,694 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 355 days; Days to treatment end: 432 days (1.2 years); Number of cycles: 4; Treatment dose: 100 mg/m2; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 355 days; Days to treatment end: 355 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 377 days (1.0 years); Days to treatment end: 377 days (1.0 years); Number of cycles: 1; Treatment dose: 120 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 397 days (1.1 years); Days to treatment end: 467 days (1.3 years); Number of cycles: 5; Treatment dose: 1,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 530 days (1.5 years); Days to treatment end: 576 days (1.6 years); Treatment dose: 20 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 576 days (1.6 years); Days to treatment end: 604 days (1.7 years); Number of cycles: 2; Treatment dose: 40 mg/m2; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.8 years (19,284 days); Days to diagnosis: 341 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 341 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 341 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 341 days; Evidence of recurrence type: Physical Examination.
- Days to follow up: 376 days (1.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Physical Examination; Timepoint: Post Initial Treatment.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-29-1775-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5.
  Slide TCGA-29-1775-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 5.
- Sample TCGA-29-1775-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Bevacizumab vs Placebo.
- Drug treatment 4, Route of administrations: Route of administration: IP.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Gemcitabine HCL.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 376 days; disease-specific survival: no event (censored), 376 days; disease-free interval: event (new tumor event after initially disease-free), 341 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 341 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1775-01A-01D-0577-01): tumor purity 0.91, ploidy 3.3, whole-genome doublings 1.
